Somatic mutation profile of tumor specimen TCGA-DD-A11C-01A (aliquot TCGA-DD-A11C-01A-11D-A12Z-10) from TCGA case TCGA-DD-A11C, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 69.5 years (25,403 days).
Specimen TCGA-DD-A11C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2d526d4-2ecc-4f44-a38b-fee7f45c8e9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A11C-11A (Solid Tissue Normal), aliquot TCGA-DD-A11C-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b6d7b665-fd32-40dc-a7ac-44f87c30c330

The open-access MAF lists 107 somatic variants for this specimen: 77 protein-altering or splice-affecting, 30 silent.
By variant classification: Missense Mutation 69, Silent 30, Frame Shift Del 3, Nonsense Mutation 2, Nonstop Mutation 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASNS | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs568570377, COSV51552688; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12499C>T p.H4167Y | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs547117792, COSV101447126, COSV71290426; called by muse, mutect2, varscan2
- ACLY | c.3184G>A p.V1062M | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1447515027, COSV59862362; called by muse, mutect2, varscan2
- ACTC1 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 60/84 reads (71%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.997); catalogued as rs1368192263, COSV51759788; called by muse, mutect2, varscan2
- ADGRE1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs747164531, COSV51673857, COSV99165427; called by muse, mutect2
- ADGRG5 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61083729; called by muse, mutect2, varscan2
- ALKBH3 | c.547A>T p.N183Y | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV57024848; called by muse, mutect2, varscan2
- ALKBH4 | c.315G>T p.R105S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV52961281; called by muse, mutect2, varscan2
- ANKRD12 | c.2260A>T p.I754F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as COSV50830737; called by muse, mutect2, varscan2
- ANKRD34A | c.1403T>A p.L468* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as COSV60161252; called by muse, mutect2, varscan2
- AREL1 | c.1091T>A p.V364E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV62666902; called by muse, mutect2, varscan2
- ASPHD1 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV58100726; called by muse, mutect2, varscan2
- ATG2B | c.1795A>C p.S599R | Missense Mutation (SNP) | VAF 48/79 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as COSV63423983; called by muse, mutect2, varscan2
- C5 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs753870842, COSV56329014; called by muse, mutect2, varscan2
- CALCA | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV59028086; called by muse, mutect2, varscan2
- CCDC197 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 29/37 reads (78%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV58939620; called by muse, mutect2, varscan2
- CFAP57 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100993994, COSV65264736; called by muse, mutect2, varscan2
- CMBL | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV56983948; called by muse, mutect2, varscan2
- CNGA1 | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV62054912; called by muse, mutect2, varscan2
- CNTNAP3 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 78/466 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs747808450, COSV99905530, COSV99905575; called by muse, varscan2
- COL6A3 | c.4904A>G p.K1635R | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99800856; called by muse, varscan2
- CSGALNACT2 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV65675917; called by muse, mutect2, varscan2
- DCUN1D4 | c.877T>C p.*293Qext*82 (on ENST00000334635 / NM_001287757.1; = p.*258Qext*82 on NM_015115.3) | Nonstop Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV58123546; called by muse, mutect2, varscan2
- DUS1L | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as rs746363915, COSV57649730; called by muse, mutect2, varscan2
- EFEMP1 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs746366927, COSV62616719; called by muse, mutect2, varscan2
- EXOC3L2 | c.1508C>A p.P503Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as COSV52972374; called by muse, varscan2
- FGFBP1 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV52586705; called by muse, mutect2, varscan2
- FLG | c.7187A>G p.H2396R | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV64243498; called by muse, mutect2, varscan2
- GBP2 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as rs200077424, COSV65068494; called by muse, mutect2, varscan2
- GUF1 | c.1740A>T p.K580N | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV55783294; called by muse, mutect2, varscan2
- HP | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 96/359 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.049); catalogued as rs373168016, COSV100577618; called by muse, mutect2
- IL12RB1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV59097757; called by muse, mutect2, varscan2
- KIF13B | c.3365A>G p.D1122G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV72954481; called by muse, varscan2
- KIF21B | c.2533G>T p.D845Y | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV59760205; called by muse, mutect2, varscan2
- KIF22 | c.1875C>A p.H625Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as rs752878228, COSV50716083; called by muse, mutect2, varscan2
- LRP1 | c.2293G>T p.V765F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV54515907; called by muse, mutect2, varscan2
- MAB21L1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs771150876, COSV59769415; called by muse, mutect2, varscan2
- MRPL22 | c.593G>A p.R198H | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as rs1363472101, COSV54557983; called by muse, mutect2, varscan2
- NUP153 | c.1816G>C p.G606R | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV50452198; called by muse, mutect2, varscan2
- NYNRIN | c.3302T>C p.M1101T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs768638091, COSV66843269; called by muse, mutect2, varscan2
- OR2J3 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65849226; called by muse, mutect2, varscan2
- OR4D2 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV73459792; called by muse, mutect2, varscan2
- PKD1 | c.9806G>T p.R3269L | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550467690, COSV51919121; called by muse, mutect2, varscan2
- PLEKHM3 | c.524A>G p.Q175R | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV66817124; called by muse, mutect2, varscan2
- PPIP5K1 | c.3688G>C p.E1230Q (on ENST00000396923; = p.E1205Q on NM_014659.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV55810152; called by muse, mutect2, varscan2
- PPP2R1A | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59045721, COSV59046160; called by muse, mutect2, varscan2
- PRAMEF2 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1254108445, COSV53576647; called by muse, mutect2, varscan2
- PREX2 | c.3063A>T p.E1021D | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV55779537; called by muse, mutect2, varscan2
- PRKDC | c.2276G>A p.G759D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58056126; called by muse, mutect2, varscan2
- PTPN14 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.798); catalogued as rs200947677; called by muse, mutect2, varscan2
- PTPRT | c.3859T>C p.Y1287H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV61992191; called by muse, mutect2, varscan2
- RBBP5 | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV52705326; called by muse, mutect2, varscan2
- RGS22 | c.24G>T p.A8= | Splice Region (SNP) | VAF 31/52 reads (60%) | catalogued as COSV62663627; called by muse, mutect2, varscan2
- RHBDF1 | c.1209-1G>A p.X403_splice | Splice Site (SNP) | VAF 20/40 reads (50%) | catalogued as COSV51956322; called by muse, mutect2, varscan2
- RING1 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV63002674; called by muse, mutect2
- RNF216 | c.2467A>G p.M823V (on ENST00000425013 / NM_207116.3; = p.M880V on NM_207111.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs757045404, COSV66291254; called by muse, mutect2, varscan2
- RRP1B | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 95/180 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV61479429; called by muse, mutect2, varscan2
- SLC19A2 | c.280T>C p.Y94H | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52547964; called by muse, varscan2
- SLC44A2 | c.1943G>A p.G648D | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV59837534; called by muse, mutect2, varscan2
- SPEN | c.4923T>G p.S1641R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV65363725; called by muse, mutect2, varscan2
- SUCLG1 | c.590G>A p.G197D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs1250026848, COSV67265373; called by muse, mutect2, varscan2
- TASP1 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV61813741; called by muse, varscan2
- TENM2 | c.6157A>G p.N2053D (on ENST00000518659 / NM_001122679.2; = p.N1814D on NM_001080428.3) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1433586017, COSV69133798; called by muse, mutect2, varscan2
- TENM3 | c.4432G>C p.A1478P | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV69311728; called by muse, mutect2, varscan2
- TMEM254 | c.291G>C p.W97C | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64845854; called by muse, mutect2, varscan2
- TRDN | c.651G>T p.K217N | Missense Mutation (SNP) | VAF 192/226 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs781233223, COSV62124810; called by muse, mutect2, varscan2
- TTC3 | c.5905G>A p.V1969M | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as rs200071342, COSV61292220; called by muse, mutect2, varscan2
- TTPAL | c.46T>G p.S16A | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.079); catalogued as COSV52829161; called by muse, mutect2, varscan2
- USP43 | c.1177C>T p.H393Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.059); catalogued as COSV53306909; called by mutect2, varscan2
- WDR17 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV54576835; called by muse, mutect2, varscan2
- ZBTB7C | c.1681C>T p.R561C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs775360190, COSV59689460; called by muse, mutect2, varscan2
- ZNF214 | c.1749A>C p.K583N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV53482520; called by muse, mutect2, varscan2
- ZNF695 | c.254A>G p.H85R | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.227); catalogued as COSV60586408; called by muse, mutect2
- ZNF804B | c.3877C>T p.P1293S | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60834389; called by muse, mutect2, varscan2
- CISH | c.706del p.A236Pfs*165 (on ENST00000348721 / NM_145071.4; = p.A253Pfs*165 on NM_013324.6) | Frame Shift Del (DEL) | VAF 40/73 reads (55%) | called by mutect2, pindel, varscan2
- OTX1 | c.313_314del p.S105Pfs*35 | Frame Shift Del (DEL) | VAF 17/82 reads (21%) | called by pindel, varscan2
- VCL | c.451del p.V151Wfs*18 | Frame Shift Del (DEL) | VAF 51/107 reads (48%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.3102G>A p.S1034= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs140287471; called by muse, mutect2, varscan2
- ARHGAP31 | c.216C>G p.G72= | Silent (SNP) | VAF 52/79 reads (66%) | catalogued as COSV51795010; called by muse, mutect2, varscan2
- CASP7 | c.99G>A p.P33= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs1317524156, COSV61882212; called by muse, mutect2, varscan2
- COL11A1 | c.2247C>T p.P749= | Silent (SNP) | VAF 16/19 reads (84%) | catalogued as COSV62187395; called by muse, mutect2, varscan2
- CTNND1 | c.1275C>T p.H425= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs759069892, COSV100650294, COSV62384308; called by muse, mutect2, varscan2
- FAM20B | c.39C>T p.L13= | Silent (SNP) | VAF 70/192 reads (36%) | catalogued as COSV55380954; called by muse, mutect2, varscan2
- GAL3ST3 | c.657C>T p.D219= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV61748790; called by muse, mutect2, varscan2
- GNGT2 | c.150C>T p.L50= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as COSV55929921, COSV55930085; called by muse, mutect2, varscan2
- GRM5 | c.888G>A p.A296= | Silent (SNP) | VAF 69/130 reads (53%) | catalogued as rs778245409, COSV59611642; called by muse, mutect2, varscan2
- HAUS5 | c.369G>A p.Q123= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV52548413; called by muse, mutect2, varscan2
- ICAM5 | c.1827G>A p.V609= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs771282852, COSV55747786; called by muse, mutect2, varscan2
- IFT80 | c.2323T>C p.L775= | Silent (SNP) | VAF 112/176 reads (64%) | catalogued as COSV58448986; called by muse, mutect2, varscan2
- KIAA2026 | c.5733C>A p.L1911= | Silent (SNP) | VAF 27/47 reads (57%) | catalogued as rs535663249, COSV67355975, COSV67358299; called by muse, mutect2, varscan2
- KRTAP5-1 | c.261G>T p.G87= | Silent (SNP) | VAF 58/140 reads (41%) | catalogued as COSV66299068; called by muse, mutect2, varscan2
- LRRC4C | c.192G>A p.R64= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV53417133; called by muse, mutect2, varscan2
- PAK2 | c.1242G>A p.V414= | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as COSV59082367, COSV59084281; called by muse, mutect2, varscan2
- PALD1 | c.2334T>C p.Y778= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs771419930, COSV54975101; called by muse, mutect2, varscan2
- PDCD11 | c.238C>T p.L80= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as rs1231896341, COSV63934334; called by muse, mutect2, varscan2
- PHC2 | c.1587C>T p.T529= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs370099521, COSV57105436; called by muse, mutect2, varscan2
- PPP2R5D | c.828C>T p.I276= | Silent (SNP) | VAF 64/115 reads (56%) | catalogued as COSV55151027; called by muse, mutect2, varscan2
- PSD2 | c.207T>C p.H69= | Silent (SNP) | VAF 82/154 reads (53%) | catalogued as COSV51202874; called by muse, mutect2, varscan2
- RBM6 | c.1893G>A p.R631= | Silent (SNP) | VAF 32/47 reads (68%) | catalogued as COSV56484517; called by muse, mutect2, varscan2
- SATB1 | c.933T>A p.P311= | Silent (SNP) | VAF 54/94 reads (57%) | catalogued as COSV58670537; called by muse, mutect2, varscan2
- SLC12A1 | c.2715A>G p.K905= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV66793034; called by muse, mutect2
- SORL1 | c.946T>C p.L316= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as COSV52756698; called by muse, mutect2, varscan2
- TAL1 | c.669C>T p.L223= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as rs1430617279, COSV53747378; called by muse, mutect2, varscan2
- TANC1 | c.3039C>T p.H1013= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs756778043, COSV55090603; called by muse, mutect2, varscan2
- TMEM225 | c.615T>A p.R205= | Silent (SNP) | VAF 82/182 reads (45%) | catalogued as rs369698336, COSV66693586; called by muse, mutect2, varscan2
- USP40 | c.3204C>T p.D1068= | Silent (SNP) | VAF 8/8 reads (100%) | catalogued as rs369926451; called by muse, mutect2
- VANGL2 | c.270C>T p.R90= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs1221733297, COSV63604789; called by muse, mutect2, varscan2
